TARGET case TARGET-10-PASWUH — Acute Lymphoblastic Leukemia - Phase II (TARGET-ALL-P2)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a73ce3b0-4223-5d7d-ba63-d1956d395349

Demographics
Sex at birth: female; Race: asian; Ethnicity: not hispanic or latino; Age at index: 9 years; Vital status: Alive.

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 9.6 years (3,524 days); Year of diagnosis: 2009; Days to last follow up: 2,072 days (5.7 years).
   Treatment given: Protocol identifier: AALL0331.

Follow-up (2 entries)
- Days to follow up: 33 days; Days to first event: 33 days; First event: Induction Failure.
- Days to follow up: 2,072 days (5.7 years); Year of follow up: 2015.

Molecular and laboratory tests (laboratory values grouped by visit day)
- BCR–ABL1 fusion: Negative.
- ETV6–RUNX1 fusion (FISH): Negative.
- KMT2A rearrangement (FISH): Negative.
- Trisomy 10: Negative.
- Trisomy 4: Negative.
- Day 0: Leukocytes 42.5 ×10³/µL.
- Day 8: Bone Marrow blast count 65%; Minimal Residual Disease (Flow Cytometry) 7.7%.
- Day 15: Bone Marrow blast count 60%.
- Day 29: Bone Marrow blast count 70%; Minimal Residual Disease (Flow Cytometry) 77.2%.

Biospecimens (2 samples)
- Sample TARGET-10-PASWUH-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
- Sample TARGET-10-PASWUH-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_II_Discovery_20230727.xlsx:
- Overall Survival Time in Days: 2072
- WBC at Diagnosis: 42.5
- CNS Status at Diagnosis: CNS 1
- MRD Day 8: 7.7
- MRD Day 8 Sensitivity: 0.01
- MRD Day 29: 77.2
- Bone Marrow Site of Relapse: No
- CNS Site of Relapse: No
- Testes Site of Relapse: No
- Other Site of Relapse: No
- ETV6 RUNX1 Fusion Status: Negative
- TRISOMY 4 10 Status: Negative
- MLL Status: Negative
- BCR ABL1 Status: Negative
- BMA Blasts Day 8: 65
- BMA Blasts Day 15: 60
- BMA Blasts Day 29: 70
- Karyotype: 46,XX[20]
- Down Syndrome: No
- DNA Index: 1
- Cell of Origin: B-Precursor
- ALL Molecular Subtype: None of the above
